Somatic mutation profile of tumor specimen HTMCP-03-06-02368-01A (aliquot HTMCP-03-06-02368-01A-01D-10409) from CGCI case HTMCP-03-06-02368, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02368-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f79517ba-6d9e-4e5e-9982-d435f64260a1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02368-10A (Blood Derived Normal), aliquot HTMCP-03-06-02368-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df359d50-0d40-48d0-8b54-5947e2815bc9

The open-access MAF lists 64 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 17, Nonsense Mutation 6, Intron 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 17/102 reads (17%) | catalogued as rs398123903, CM070907; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- ABCA13 | c.5635C>T p.R1879* | Nonsense Mutation (SNP) | VAF 15/119 reads (13%) | catalogued as rs369928374; called by mutect2, varscan2
- CEP85 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs778449958; called by mutect2, varscan2
- CHD7 | c.5740C>T p.R1914C | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373823856; called by muse, mutect2, varscan2
- CNTNAP2 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs752756517, COSV62253518, COSV62260875; called by mutect2, varscan2
- FCGR2A | c.196C>T p.R66C (on ENST00000271450 / NM_001136219.3; = p.R65C on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1257003455, COSV54837274; called by muse, mutect2, varscan2
- FN1 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs774390890, COSV100117692; called by mutect2, varscan2
- KCND1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as rs782341099; called by muse, mutect2
- MIER1 | c.712G>A p.E238K (on ENST00000355356 / NM_001077701.3; = p.E255K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100591288; called by muse, mutect2
- MYH6 | c.4822C>T p.R1608C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201683868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAP1L3 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1354915707; called by muse, mutect2
- NOL8 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.143); catalogued as COSV100694539; called by muse, mutect2, varscan2
- PEG3 | c.4216G>T p.V1406L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs746934903; called by mutect2, varscan2
- PIKFYVE | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as COSV52247096; called by muse, mutect2, varscan2
- PPP2R2B | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs183660844; called by mutect2, varscan2
- RLIM | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.996); catalogued as COSV60328669; called by muse, mutect2, varscan2
- SRCAP | c.6439C>T p.Q2147* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV52672429; called by muse, mutect2, varscan2
- SYCP2 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1024601070; called by muse, mutect2, varscan2
- TENM1 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100950914; called by muse, mutect2
- TNXB | c.5104G>A p.V1702M (on ENST00000647633; = p.V1455M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs572455281, COSV64474764; called by muse, mutect2, varscan2
- TTN | c.53629G>A p.E17877K (on ENST00000591111; = p.E10453K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/130 reads (15%) | PolyPhen probably damaging (0.994); catalogued as rs1329313961; called by muse, mutect2, varscan2
- TTN | c.28375G>A p.E9459K (on ENST00000591111; = p.E8532K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/190 reads (12%) | PolyPhen benign (0); catalogued as rs143477225, COSV60187778; called by muse, mutect2, varscan2
- USP26 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.175); catalogued as COSV63708002, COSV63708086; called by muse, mutect2
- ZFYVE26 | c.6422C>T p.T2141M | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs146308319; called by muse, mutect2, varscan2
- ZNF665 | c.685G>A p.E229K (on ENST00000600412; = p.E294K on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV67214345; called by muse, mutect2, varscan2
- AK7 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); called by muse, mutect2
- ARID2 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); called by mutect2, varscan2
- FLG2 | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR158 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- IRAG1 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRF1 | c.7_30del p.I3_P10del | In Frame Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- KNTC1 | c.6551C>G p.S2184* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- LRP2 | c.4554G>A p.W1518* | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- MIA3 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2
- MTPAP | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- MUC16 | c.15457C>G p.Q5153E | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NALCN | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PKHD1 | c.10923G>A p.M3641I | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- STYXL2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- SYNE2 | c.8507G>T p.R2836I | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- TNS2 | c.3644G>A p.G1215D (on ENST00000314250 / NM_170754.4; = p.G1225D on NM_015319.2) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- WNK3 | c.4474G>A p.E1492K | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2
- ZNF649 | c.1097G>A p.R366K | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ATM | c.955C>T p.L319= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- CUL7 | c.663G>A p.L221= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- DACH2 | c.882G>A p.G294= | Silent (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- DPP10 | c.1690C>T p.L564= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV100058462, COSV59685552; called by muse, mutect2, varscan2
- ERC2 | c.1974G>A p.L658= | Silent (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2, varscan2
- FARP1 | c.2970G>A p.E990= | Silent (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- FMN2 | c.4668C>G p.L1556= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV60425626; called by muse, mutect2, varscan2
- HEG1 | c.1098C>T p.A366= | Silent (SNP) | VAF 24/214 reads (11%) | called by muse, mutect2, varscan2
- LCT | c.4269C>T p.D1423= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as rs773638318; called by muse, mutect2, varscan2
- PDHA1 | c.198G>A p.R66= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs1209667020; called by muse, mutect2, varscan2
- RFX7 | c.3687C>A p.I1229= (on ENST00000559447 / NM_001368074.1; = p.I1326= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/282 reads (11%) | called by muse, mutect2, varscan2
- STXBP5L | c.3420G>A p.R1140= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV56516425; called by mutect2, varscan2
- TGM4 | c.1470C>T p.F490= | Silent (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2
- THADA | c.3780G>A p.L1260= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.13029G>A p.T4343= (on ENST00000591111; = p.T4297= on NM_003319.4) | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as rs1384061855; called by muse, mutect2, varscan2
- WDR45 | c.135C>T p.H45= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs782629776; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZFHX4 | c.4557G>A p.R1519= | Silent (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- AC092865.4 | chr12:8390838 G>C | 5'Flank (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- ZBTB17 | c.1372-90G>C | Intron (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- ZNF208 | c.226+165T>G | Intron (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
